Gene-level copy-number profile of tumor specimen TARGET-20-PASBSB-03A from TARGET case TARGET-20-PASBSB, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.1 years (6,241 days).
Specimen TARGET-20-PASBSB-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-AML.a466b036-3105-5f79-a92f-a7898ef9c83e.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-20-PASBSB-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 352 have no estimate.
https://portal.gdc.cancer.gov/files/231a60dd-4b7c-4004-b488-91c6026012c6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 529; copy number 1: 353; copy number 2: 57,231; copy number 3: 2,093; copy number 4: 60; copy number 5: 5.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,614,098, 2 genes: LCE3C, LCE3B.
- chr4:10,199,823–10,268,231, 5 genes: AC006499.1, AC006499.8, RAF1P1, AC006499.4, AC006499.2.
- chr12:5,226,196–5,244,199, 1 gene: LINC02443.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:2,088,933–2,089,211, 1 gene, copy number 5: RN7SKP144.
- chr3:96,753,185–96,814,407, 3 genes, copy number 5: RCC2P5, CDV3P1, AC109782.1.
- chr8:4,633,065–4,635,654, 1 gene, copy number 5: AC022068.1.

Autosomal genes at a single copy (total copy number 1): 348. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
